Somatic mutation profile of tumor specimen TCGA-ER-A19B-06A (aliquot TCGA-ER-A19B-06A-11D-A196-08) from TCGA case TCGA-ER-A19B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 48.4 years (17,664 days).
Specimen TCGA-ER-A19B-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2896a52-686c-4247-82c6-8e27c900fb6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19B-10A (Blood Derived Normal), aliquot TCGA-ER-A19B-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b340437-8656-4fd3-adce-83d956d2a9b0

The open-access MAF lists 121 somatic variants for this specimen: 85 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 33, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, RNA 2, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2732+2T>C p.X911_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | hotspot (GDC flag); catalogued as COSV61374491; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/102 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABHD11 | c.839T>C p.M280T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56105529; called by muse, mutect2, varscan2
- AC109583.1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV58405450; called by muse, mutect2
- AHCYL2 | c.1295+2T>C p.X432_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | catalogued as COSV61486160; called by muse, mutect2
- ANKRD12 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746386764, COSV50821382; called by muse, mutect2
- ARHGEF10 | c.1481C>T p.S494F (on ENST00000398564; = p.S469F on NM_014629.4) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV50645047; called by muse, varscan2
- BAZ1B | c.4138A>G p.I1380V | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV59989934; called by muse, mutect2, varscan2
- BCORL1 | c.2518T>C p.S840P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.051); catalogued as COSV54392978; called by muse, mutect2, varscan2
- CABP1 | c.1023C>A p.H341Q (on ENST00000316803 / NM_001033677.1; = p.H138Q on NM_004276.5) | Missense Mutation (SNP) | VAF 105/496 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV56458104; called by muse, mutect2, varscan2
- CCRL2 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.423); catalogued as COSV62193323; called by muse, mutect2, varscan2
- CHST4 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as rs753717064, COSV58296739; called by muse, varscan2
- CIP2A | c.1858T>C p.S620P | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417920; called by muse, mutect2
- CNTN2 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59349128; called by muse, mutect2, varscan2
- DCP1B | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54968174; called by muse, mutect2, varscan2
- DLX1 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776516857, COSV59394196; called by muse, mutect2, varscan2
- DMRTA2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV68672557; called by muse, mutect2, varscan2
- DNAH9 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs866851408, COSV52343092; called by mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV62567201; called by muse, mutect2, varscan2
- EEPD1 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs1562666308, COSV54196961; called by muse, mutect2, varscan2
- ERN1 | c.365A>G p.Q122R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV70501258; called by muse, mutect2, varscan2
- EXO1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs567681802, COSV62217034; called by muse, mutect2, varscan2
- FAM104A | c.58T>A p.Y20N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.181); catalogued as COSV52145682; called by mutect2, varscan2
- GIMAP5 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs765707928, COSV57529845; called by muse, mutect2, varscan2
- GPR20 | c.1058C>G p.A353G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.111); catalogued as COSV66684183; called by muse, mutect2, varscan2
- H4C3 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779327642, COSV58090237; called by muse, mutect2, varscan2
- HEATR1 | c.6236A>G p.K2079R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV59381054; called by muse, mutect2, varscan2
- IFRD1 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV50043893; called by muse, mutect2, varscan2
- IFT140 | c.2106G>C p.E702D | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV68487100; called by muse, mutect2, varscan2
- IGHG3 | c.1298C>A p.T433N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs765963760; called by muse, mutect2, varscan2
- ILF2 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV62627104; called by muse, mutect2, varscan2
- KCNH2 | c.2486A>G p.D829G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51132075; called by muse, mutect2, varscan2
- KIF20B | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV53304844; called by muse, mutect2, varscan2
- KLHDC7A | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV68769363; called by muse, mutect2, varscan2
- KLHL17 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58531278; called by muse, mutect2, varscan2
- LAMA1 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV67534470; called by muse, mutect2, varscan2
- LIPT1 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV60739480; called by muse, mutect2, varscan2
- LRRIQ1 | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV67812824; called by muse, mutect2, varscan2
- LRRN1 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.715); catalogued as COSV60013205; called by mutect2, varscan2
- MAP4K1 | c.2501A>G p.*834Wext*37 | Nonstop Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV62093518; called by muse, mutect2, varscan2
- MCEE | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 43/230 reads (19%) | catalogued as COSV54905533; called by muse, mutect2, varscan2
- MCTP1 | c.2636A>G p.N879S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs1317142465, COSV56510116; called by muse, mutect2, varscan2
- MINDY1 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV56498137; called by muse, mutect2, varscan2
- MKRN1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55436275; called by muse, varscan2
- MON1B | c.1633A>G p.T545A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.13); catalogued as COSV50245891; called by muse, mutect2
- MUCL1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs147966123; called by muse, varscan2
- NAV1 | c.3508A>G p.T1170A | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV55215787; called by muse, mutect2, varscan2
- NKX2-2 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV65819341; called by muse, mutect2, varscan2
- OLR1 | c.473T>C p.F158S | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58871144; called by muse, mutect2, varscan2
- OR8B4 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.208); catalogued as COSV62069551; called by muse, mutect2, varscan2
- PCDH7 | c.2810A>G p.D937G | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.758); catalogued as COSV62337733; called by muse, mutect2, varscan2
- PHTF1 | c.1093T>C p.S365P | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV63367142; called by muse, varscan2
- PLEKHA7 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs756338340, COSV63044785; called by mutect2, varscan2
- POLR3H | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53442086; called by muse, mutect2, varscan2
- PRG4 | c.2092C>G p.P698A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs776073497, COSV63355195; called by muse, varscan2
- PSG6 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51831706; called by muse, mutect2, varscan2
- RAB1B | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1340993943, COSV57582065; called by muse, mutect2, varscan2
- RNF182 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70368915; called by muse, mutect2, varscan2
- SEC23B | c.1666T>G p.C556G | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV52719411; called by muse, mutect2, varscan2
- SGCE | c.1495T>C p.Y499H (on ENST00000647096; = p.Y436H on NM_003919.3) | Missense Mutation (SNP) | VAF 88/589 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1265642982, COSV56016285; called by muse, mutect2, varscan2
- SLC4A10 | c.1289G>A p.G430E (on ENST00000446997 / NM_001354461.2; = p.G400E on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55771916; called by muse, varscan2
- SLC5A8 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746671357, COSV101610593, COSV73310486; called by muse, varscan2
- SOS2 | c.2921A>G p.N974S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV53565736; called by muse, mutect2, varscan2
- SPAG17 | c.4102C>T p.H1368Y | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV60455956; called by muse, mutect2, varscan2
- STX12 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64249162; called by muse, varscan2
- STYXL1 | c.814T>G p.S272A | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50388229; called by muse, varscan2
- TANC1 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1425593535, COSV55082824, COSV55093743; called by mutect2, varscan2
- TEKT3 | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100106684, COSV58626955; called by mutect2, varscan2
- TG | c.4831G>A p.E1611K | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs747788493, COSV55070941; called by mutect2, varscan2
- THAP8 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs558187466, COSV53077733, COSV99495700, COSV99495850; called by mutect2, varscan2
- THSD7A | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV70262830; called by muse, varscan2
- TLR7 | c.551A>T p.Y184F | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV66123921; called by muse, mutect2, varscan2
- TRANK1 | c.4781C>T p.S1594F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57145729; called by mutect2, varscan2
- TRHDE | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV53837789; called by muse, mutect2, varscan2
- TULP2 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV55477409; called by muse, mutect2, varscan2
- USP37 | c.1310T>C p.L437S | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51442408; called by muse, varscan2
- VWA7 | c.513+2T>A p.X171_splice | Splice Site (SNP) | VAF 36/95 reads (38%) | catalogued as COSV63304390; called by muse, mutect2, varscan2
- WRAP73 | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV54560650; called by muse, mutect2, varscan2
- ZBTB16 | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60091105; called by muse, mutect2, varscan2
- ZCCHC12 | c.813C>G p.D271E | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV59571255, COSV59572524; called by muse, mutect2, varscan2
- ZNF112 | c.2188T>A p.F730I (on ENST00000337401 / NM_001083335.2; = p.F724I on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61619448; called by mutect2, varscan2
- ZSWIM5 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV62733494; called by muse, mutect2
- CPEB1 | c.1838A>G p.H613R (on ENST00000617958; = p.H548R on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POLG | c.553del p.V185Yfs*81 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- RNF169 | c.1575del p.L526Wfs*26 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- ADCY9 | c.3441C>T p.R1147= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs376101747; called by muse, mutect2, varscan2
- AXDND1 | c.2862T>C p.H954= | Silent (SNP) | VAF 6/125 reads (5%) | catalogued as COSV62641123; called by muse, mutect2
- CNTN2 | c.1230A>G p.L410= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV59349173; called by muse, mutect2
- DENND4C | c.5413C>T p.L1805= (on ENST00000434457 / NM_001330640.2; = p.L1756= on NM_017925.7) | Silent (SNP) | VAF 62/94 reads (66%) | catalogued as COSV63008574; called by muse, mutect2, varscan2
- DNAH9 | c.6354G>A p.A2118= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs746466572, COSV52336163; called by mutect2, varscan2
- DNER | c.411C>A p.P137= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV59163153; called by muse, mutect2, varscan2
- FAAH | c.1734A>G p.S578= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1463428282, COSV99680120; called by muse, varscan2
- GABPB2 | c.867C>T p.I289= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV64460661; called by muse, mutect2, varscan2
- GABRB3 | c.1362C>T p.I454= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs745449592, COSV100162335, COSV54657356; called by mutect2, varscan2
- GANC | c.207T>C p.P69= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100530996; called by muse, mutect2
- GREB1 | c.4056A>G p.T1352= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV52183916; called by muse, mutect2, varscan2
- GYS2 | c.1182T>C p.H394= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV53921763; called by muse, varscan2
- HDAC2 | c.81G>A p.Q27= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV64037694; called by muse, mutect2, varscan2
- HSPB8 | c.210C>G p.P70= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV56137436; called by muse, varscan2
- IK | c.903G>A p.K301= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV70257554; called by muse, mutect2, varscan2
- KDM6B | c.2769C>T p.T923= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV54679757; called by muse, varscan2
- MYEF2 | c.1215C>T p.Y405= | Silent (SNP) | VAF 63/255 reads (25%) | catalogued as COSV51046799; called by muse, mutect2, varscan2
- NEDD1 | c.156A>G p.A52= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs758103005, COSV57142527; called by muse, mutect2, varscan2
- PHLDB2 | c.141G>A p.L47= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV67309728; called by muse, mutect2, varscan2
- PLPPR2 | c.603G>A p.A201= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs756982148, COSV52259287; called by mutect2, varscan2
- PMS1 | c.1503A>G p.G501= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV59715600; called by muse, mutect2, varscan2
- PRPSAP1 | c.1014T>C p.N338= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs540872123, COSV53152169; called by muse, mutect2, varscan2
- PSG6 | c.360C>T p.T120= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as rs761696551, COSV51831738; called by muse, mutect2, varscan2
- RAB34 | c.400C>T p.L134= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV56385804, COSV99973123; called by muse, mutect2, varscan2
- RPL3 | c.432G>A p.K144= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV53365008; called by muse, mutect2, varscan2
- RTTN | c.4506T>C p.C1502= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV55343097; called by muse, mutect2, varscan2
- SERPINB7 | c.1142G>A p.*381= | Silent (SNP) | VAF 36/42 reads (86%) | catalogued as COSV60532624; called by mutect2, varscan2
- SRRM3 | c.1695G>A p.R565= | Silent (SNP) | VAF 21/22 reads (95%) | catalogued as COSV58386464; called by muse, mutect2, varscan2
- STON1 | c.1503C>T p.I501= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs769953627, COSV59128556; called by muse, mutect2, varscan2
- TMEM214 | c.1725C>T p.F575= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV53192160; called by muse, mutect2, varscan2
- TNF | c.120C>T p.I40= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs141667614; called by mutect2, varscan2
- UNC5C | c.927T>C p.C309= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV71658895; called by muse, mutect2, varscan2
- ZFHX4 | c.8571G>A p.T2857= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs866211874, COSV50653119; called by muse, mutect2, varscan2
- HERC2P3 | n.52C>G | RNA (SNP) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- KCNIP2 | c.765+22A>G | Intron (SNP) | VAF 10/43 reads (23%) | called by mutect2, varscan2
- TBC1D29P | n.2841G>A | RNA (SNP) | VAF 6/31 reads (19%) | catalogued as COSV70433943; called by muse, mutect2, varscan2
